FM case AD8058 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/27c3742d-dd3a-49c3-bfb9-149959691594

Female, 54.2 years: Ependymoma, NOS (ICD-O-3 9391/3) of the nervous system; metastasis biopsied or resected from the vertebral column. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
